BEATAML1.0 case 2098 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/87268ac4-9c03-4ddc-b9ff-32b86b4a394b

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute megakaryoblastic leukaemia: ICD-O-3 morphology code: 9910/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (665 days); Progression or recurrence: yes; ELN risk classification: Adverse.

Biospecimens (1 sample)
- Sample BA2164D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
